Somatic mutation profile of tumor specimen fbb41c94-aabd-49cc-90b2-882c3e (aliquot fbb41c94-aabd-49cc-90b2-882c3e_D6) from CPTAC case 02OV008, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen fbb41c94-aabd-49cc-90b2-882c3e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 008b1ba0-c595-430f-b9dc-906e9d0ca4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5ffd8c6c-0807-4be5-b0d1-dc475f (Blood Derived Normal), aliquot 5ffd8c6c-0807-4be5-b0d1-dc475f_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65b8a0b-a873-44b4-9191-b2073a0b23b2

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 12, Frame Shift Del 4, 3'UTR 3, In Frame Del 3, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 383/638 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139262121; called by muse, mutect2, varscan2
- ARV1 | c.448+2T>A p.X150_splice | Splice Site (SNP) | VAF 24/148 reads (16%) | catalogued as COSV59618027; called by muse, mutect2, varscan2
- ESYT3 | c.1547_1549del p.S516del | In Frame Del (DEL) | VAF 28/205 reads (14%) | catalogued as rs776044854; called by mutect2, pindel, varscan2
- GPR85 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as COSV51785996; called by muse, mutect2, varscan2
- H1-4 | c.547_549del p.K183del | In Frame Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs752969824, COSV56801123; called by mutect2, pindel, varscan2
- KLHL26 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs1466306181; called by muse, mutect2, varscan2
- NCKAP5L | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376570820; called by muse, mutect2, varscan2
- PRSS1 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs201027769; called by muse, mutect2, varscan2
- TP53I11 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57533185; called by muse, mutect2, varscan2
- TUBB4A | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 214/838 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as rs1201985530, COSV51164798; called by muse, mutect2, varscan2
- ADAMTS2 | c.2332_2336del p.E778* | Frame Shift Del (DEL) | VAF 449/722 reads (62%) | called by mutect2, pindel, varscan2
- ANO7 | c.1115G>T p.C372F (on ENST00000274979; = p.C318F on NM_001370694.2) | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BSCL2 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 142/753 reads (19%) | called by mutect2, varscan2
- CDKL1 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DEFB123 | c.25_28del p.T9Cfs*8 | Frame Shift Del (DEL) | VAF 32/213 reads (15%) | called by mutect2, pindel, varscan2
- KCTD8 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LPAR4 | c.185_188del p.F62Sfs*6 | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | called by mutect2, pindel, varscan2
- PKHD1 | c.6354_6355del p.N2119Lfs*28 | Frame Shift Del (DEL) | VAF 49/223 reads (22%) | called by pindel, varscan2
- RIN2 | c.1138C>G p.Q380E (on ENST00000255006 / NM_001242581.1; = p.Q331E on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RYR1 | c.9434_9472del p.Q3145_I3157del | In Frame Del (DEL) | VAF 100/395 reads (25%) | called by mutect2, pindel, varscan2
- S1PR1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 140/357 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SFT2D3 | c.168C>G p.S56R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, varscan2
- TEK | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 91/557 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC28 | c.6917T>C p.M2306T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST12 | c.993G>A p.P331= | Silent (SNP) | VAF 49/334 reads (15%) | catalogued as rs751420768, COSV51675662; called by muse, mutect2, varscan2
- DDX60L | c.4263A>G p.G1421= | Silent (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- DLG1 | c.1198T>C p.L400= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs546600107; called by muse, mutect2, varscan2
- KRT77 | c.1656C>T p.S552= | Silent (SNP) | VAF 114/228 reads (50%) | catalogued as rs1416378390; called by muse, mutect2, varscan2
- LMF2 | c.1995G>A p.P665= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs368866707; called by muse, mutect2, varscan2
- MCF2 | c.526C>T p.L176= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- NOX4 | c.774G>A p.P258= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as rs375572947, COSV54464478; called by muse, mutect2, varscan2
- PCDH19 | c.930C>T p.H310= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as rs376496717; called by muse, mutect2
- RET | c.906C>T p.D302= | Silent (SNP) | VAF 56/729 reads (8%) | catalogued as rs768934031; ClinVar: likely benign; called by muse, mutect2
- RNF180 | c.1638G>A p.R546= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs761928319; called by muse, mutect2, varscan2
- SERINC4 | c.183C>A p.R61= | Silent (SNP) | VAF 75/352 reads (21%) | called by muse, mutect2, varscan2
- TPSD1 | c.345C>T p.I115= | Silent (SNP) | VAF 338/705 reads (48%) | catalogued as rs139808778; called by muse, mutect2, varscan2
- ETV2 | c.*8C>A | 3'UTR (SNP) | VAF 44/177 reads (25%) | called by muse, mutect2, varscan2
- FCN1 | c.*516C>A | 3'UTR (SNP) | VAF 69/124 reads (56%) | called by muse, mutect2, varscan2
- MLIP | c.613-10947C>A | Intron (SNP) | VAF 50/268 reads (19%) | catalogued as rs1421434790; called by mutect2, varscan2
- ZRANB3 | c.*190C>T | 3'UTR (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
